Somatic mutation profile of tumor specimen TCGA-DJ-A3VB-01A (aliquot TCGA-DJ-A3VB-01A-11D-A23M-08) from TCGA case TCGA-DJ-A3VB, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, columnar cell; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 52.7 years (19,248 days).
Specimen TCGA-DJ-A3VB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 816b9cae-9658-40dc-b36c-dd83e2f0ead9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A3VB-10A (Blood Derived Normal), aliquot TCGA-DJ-A3VB-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/efc281d9-93fc-4d21-8891-a872d43a5310

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 8, Silent 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as rs79045456, COSV58559364; called by mutect2, varscan2
- GPR139 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 81/234 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746326530, COSV58503678; called by muse, mutect2, varscan2
- GRK1 | c.825C>T p.I275= | Splice Region (SNP) | VAF 7/158 reads (4%) | catalogued as COSV59553486; called by muse, mutect2
- LRPAP1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1333498195, COSV56345685; called by muse, mutect2, varscan2
- MCM4 | c.1823A>T p.N608I | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV50626574; called by muse, mutect2, varscan2
- MYCBP2 | c.4048A>G p.T1350A (on ENST00000357337; = p.T1388A on NM_015057.5) | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as rs1247007426, COSV62028001; called by muse, mutect2, varscan2
- PCBP1 | c.299T>A p.L100Q | Missense Mutation (SNP) | VAF 15/322 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1422143141, COSV57849655, COSV57849905, COSV57849936; called by muse, mutect2
- SLC40A1 | c.230C>G p.A77G | Missense Mutation (SNP) | VAF 165/490 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as CM014599, COSV53723625; called by muse, mutect2, varscan2
- CCDC60 | c.438C>T p.T146= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as rs1279207572, COSV59546749; called by muse, mutect2, varscan2
- ZNF630 | c.1695T>C p.H565= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV52097357; called by muse, mutect2
